Gene-level copy-number profile of tumor specimen HCM-BROD-0681-C71-02A from HCMI case HCM-BROD-0681-C71, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 50.2 years (18,343 days).
Specimen HCM-BROD-0681-C71-02A: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 48edff7b-0aa1-434b-961c-ca30bc4ec88c.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0681-C71-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,722 have no estimate.
https://portal.gdc.cancer.gov/files/2792f6d1-84bf-4797-bac5-1854ff6eaba4

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 151; copy number 1: 8,139; copy number 2: 42,913; copy number 3: 7,529; copy number 4: 156; copy number 12: 1; copy number 113: 11; copy number 122: 1.

Homozygous deletions (total copy number 0; autosomes only): 151 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:20,331,446–32,334,354, 139 genes (broad region; genes not listed).
- chr9:61,190,003–61,453,030, 7 genes: SPATA31A7, BX005040.3, BX005040.2, FAM74A4, BX005040.1, CNTNAP3C, RN7SL462P.
- chr10:47,995,322–48,119,455, 5 genes: FAM25C, AGAP12P, RNA5SP315, BMS1P7, PTPN20CP.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 13 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:66,797,741–66,801,256, 1 gene, copy number 122: INSL5.
- chr7:54,621,025–55,344,958, 11 genes, copy number 113: RNU6-1125P, RPL31P35, SEC61G, SEC61G-DT, AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2, AC073347.1.
- chr7:75,395,063–75,410,996, 1 gene, copy number 12 (within-gene range 3–12): TRIM73.

Autosomal genes at a single copy (total copy number 1): 5,823. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
